Gene-level copy-number profile of tumor specimen TCGA-B6-A0IQ-01A from TCGA case TCGA-B6-A0IQ, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 40.2 years (14,669 days).
Specimen TCGA-B6-A0IQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.758e3752-e267-4bb3-be83-a88b6eb7e9fc.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0IQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS (2 files); ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/421aa7a3-781f-40ed-95ea-61b61e9486bc

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 50; copy number 1: 1,539; copy number 2: 20,652; copy number 3: 22,950; copy number 4: 10,228; copy number 5: 1,051; copy number 6: 1,028; copy number 7: 1,504; copy number 8: 76; copy number 9: 358; copy number 10: 37; copy number 11: 218; copy number 12: 36; copy number 13: 19; copy number 14: 6; copy number 15: 26; copy number 18: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0IQ-01A-11D-A036-01): tumor purity 0.54, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 50 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:3,086,143–3,880,713, 46 genes (within-gene range 0–8): RNU1-22P, ZSCAN10, ZNF213-AS1, AC108134.4, ZNF205, ZNF213, CASP16P, AC108134.2, AJ003147.1, AJ003147.2, OR1F1, OR1F2P, ZNF200, MEFV, LINC00921, ZNF263, AJ003147.3, AC004232.2, TIGD7, ZNF75A, AC004232.1, AC025283.1, OR2C1, AC025283.2, MTCO1P28, MTND1P8, MTRNR2L4, ZSCAN32, ZNF174, ZNF597, NAA60, AC004224.2, MIR6126, C16orf90, AC004224.1, CLUAP1, AC004494.2, NLRC3, AC004494.1, AC006111.1, SLX4, DNASE1, AC006111.2, TRAP1, AC006111.3, CREBBP.
- chr17:61,034,636–61,135,969, 4 genes (within-gene range 0–2): AC005884.1, AC005884.2, RPL23AP74, AC005856.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,204 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–164,899,296, 895 genes, copy number 7–10 (within-gene range 4–10) (broad region; genes not listed).
- chr1:215,622,891–216,423,448, 1 gene, copy number 7 (within-gene range 6–7): USH2A.
- chr1:216,072,465–216,204,366, 3 genes, copy number 7: USH2A-AS2, USH2A-AS1, MRPS18BP1.
- chr1:221,701,424–223,845,954, 37 genes, copy number 7: DUSP10, LINC01655, RNU6-403P, LINC02257, LINC02474, LINC01705, AL356108.1, QRSL1P2, AL513314.1, CICP13, AL513314.2, RNU6-791P, AL592148.2, HHIPL2, TAF1A, TAF1A-AS1, MIA3, AL592148.1, AL592148.3, AIDA, BROX, FAM177B, AL392172.1, DISP1, NDUFB1P2, AL929091.1, TLR5, AL359979.2, AL359979.1, SUSD4, RNU4-57P, CCDC185, CAPN8, SNRPEP10, RNU6-1248P, CAPN2, TP53BP2.
- chr1:226,061,851–229,305,894, 124 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr1:232,397,965–248,919,946, 384 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr7:105,439,661–106,126,700, 12 genes, copy number 8 (within-gene range 4–8): PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2, ATXN7L1, AC005099.1, CDHR3, AC004836.1, SYPL1, DCAF13P1.
- chr7:139,133,744–143,352,083, 192 genes, copy number 7 (within-gene range 3–7) (broad region; genes not listed).
- chr10:45,099,487–67,696,195, 276 genes, copy number 10–18 (within-gene range 3–18) (broad region; genes not listed).
- chr16:3,840,528–13,779,760, 218 genes, copy number 7–14 (broad region; genes not listed).
- chr19:14,333,743–15,584,709, 62 genes, copy number 11 (within-gene range 3–11) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
